Somatic mutation profile of tumor specimen 0DHHL8 from CCDI case PBBUNK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 6.5 years (2,372 days).
Specimen 0DHHL8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35c3035a-97ef-4ee2-8606-7fa488cf7094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHHIZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0780b5b4-d2de-48d4-8318-0e9369cd5663

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Silent 3, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHR | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 343/1226 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs766592204, COSV54123303; called by muse, mutect2, varscan2
- BACH1 | c.1861T>G p.C621G | Missense Mutation (SNP) | VAF 323/1157 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- NIPBL | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 378/1044 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADRA2A | c.375G>T p.L125= | Silent (SNP) | VAF 247/711 reads (35%) | called by muse, mutect2, varscan2
- CNGA1 | c.1464C>A p.V488= | Silent (SNP) | VAF 55/1443 reads (4%) | called by muse, mutect2
- CYP17A1 | c.625C>T p.L209= | Silent (SNP) | VAF 270/879 reads (31%) | called by muse, mutect2, varscan2
- CASP1 | c.1116+45C>A | Intron (SNP) | VAF 205/652 reads (31%) | called by muse, mutect2, varscan2
- PDE4C | c.546-43C>T | Intron (SNP) | VAF 70/205 reads (34%) | catalogued as rs377670826; called by muse, mutect2, varscan2
- RFC4 | c.801+21G>C | Intron (SNP) | VAF 197/745 reads (26%) | called by muse, mutect2, varscan2
